Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A24L, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A24L-01A (Primary Tumor).

Final Diagnosis

Breast, right, wide local excision: Invasive ductal carcinoma, Nottingham grade 2 (of 3), forming a 2.5 x 2.1 x 1.0 cm mass (AJCC pT2). Ductal carcinoma in situ, solid type, without necrosis and high nuclear grade identified. Angiovascular invasion present. After, re-excision of inferior and deep margins, all margins are negative by at least 1.0 cm. Skin ellipse identified without abnormality.

Lymph nodes, right axillary sentinel, excision: Multiple (2 of 5) sentinel lymph nodes are positive for metastatic breast carcinoma (AJCC pN1).

Lymph nodes, right axillary, excision: Multiple (7) right axillary lymph nodes are negative for tumor.

Estrogen/progesterone analysis and Her2/Neu have been ordered on paraffin embedded tissue.

ICD-O-3

carcinoma, infiltrating ductal, NOS 8500/3

Site: breast, NOS C50.9 lw 4/25/11

Source: NCI Genomic Data Commons file f1d3f914-8bab-49e9-b78f-b384f6393c7d (TCGA-AR-A24L.BF82AD23-B40E-459F-83EC-590D392664FD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).